Somatic mutation profile of tumor specimen TCGA-D1-A169-01A (aliquot TCGA-D1-A169-01A-11D-A12J-09) from TCGA case TCGA-D1-A169, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 63.6 years (23,238 days).
Specimen TCGA-D1-A169-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53b793ff-4ff0-4d40-ab2a-5c69d5305ffa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A169-10A (Blood Derived Normal), aliquot TCGA-D1-A169-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89fc115b-720c-464a-8b91-216ce4d26f2a

The open-access MAF lists 62 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 37, Silent 14, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 73/165 reads (44%) | catalogued as rs121909105, CM043822, COSV52178500; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- PTEN | c.389G>C p.R130P | Missense Mutation (SNP) | VAF 96/292 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 50/95 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C14orf119 | c.56C>G p.S19* | Nonsense Mutation (SNP) | VAF 38/565 reads (7%) | catalogued as COSV52979410; called by muse, mutect2
- CACNG2 | c.297G>A p.R99= | Splice Region (SNP) | VAF 52/125 reads (42%) | catalogued as COSV55638231, COSV55638841; called by muse, mutect2, varscan2
- CAMK2B | c.1957G>A p.V653M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV51663978; called by muse, mutect2, varscan2
- CCDC184 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.024); catalogued as COSV57252304; called by muse, mutect2
- CLP1 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.895); catalogued as rs774552487, COSV57055342; called by muse, mutect2, varscan2
- CLVS2 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 146/348 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs530279493, COSV51562057; called by muse, mutect2, varscan2
- CORO1C | c.1001+1G>A p.X334_splice | Splice Site (SNP) | VAF 67/258 reads (26%) | catalogued as COSV54598005; called by muse, mutect2, varscan2
- DDX54 | c.301A>G p.M101V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs749448632, COSV58375174; called by muse, mutect2, varscan2
- EIF2AK2 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs747429747, COSV51798081; called by muse, mutect2, varscan2
- EVI2A | c.629A>C p.Q210P | Missense Mutation (SNP) | VAF 103/193 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55986638; called by muse, mutect2, varscan2
- FAT1 | c.1643_1644insA p.R549Pfs*13 | Frame Shift Ins (INS) | VAF 17/72 reads (24%) | catalogued as COSV71675309; called by mutect2, pindel*, varscan2*
- FGD1 | c.1294C>A p.H432N | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV64309293; called by muse, mutect2, varscan2
- FGF3 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV61926531; called by muse, mutect2
- FKBP15 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 60/127 reads (47%) | catalogued as rs374443474; called by muse, mutect2, varscan2
- GPN3 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as COSV57399935; called by muse, mutect2
- GPR4 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.747); catalogued as COSV59917792; called by muse, mutect2, varscan2
- ITGA11 | c.2640G>C p.E880D | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.083); catalogued as COSV59880409; called by muse, mutect2, varscan2
- ITGAL | c.721G>C p.A241P | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as COSV63323520; called by muse, mutect2, varscan2
- ITPRID2 | c.1413+2T>C p.X471_splice | Splice Site (SNP) | VAF 16/62 reads (26%) | catalogued as COSV57474802; called by muse, mutect2, varscan2
- LZTR1 | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs375451574; called by muse, mutect2, varscan2
- MAP4 | c.895G>C p.D299H | Missense Mutation (SNP) | VAF 22/520 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV64242982; called by muse, mutect2
- OR11G2 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.168); catalogued as rs760053493, COSV62132828; called by muse, mutect2, varscan2
- PCDHGA2 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.014); catalogued as COSV53899200; called by muse, mutect2, varscan2
- PIK3R1 | c.1808_1814+2del p.X603_splice (on ENST00000521381 / NM_181523.3; = p.X333_splice on NM_181504.4) | Splice Site (DEL) | VAF 88/394 reads (22%) | catalogued as COSV57135574; called by mutect2, pindel, varscan2
- PLK2 | c.245A>T p.Y82F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV57109059; called by muse, mutect2
- PRB3 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 66/395 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs754067998, COSV54389507; called by muse, mutect2, varscan2
- PRDM16 | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369644938; called by muse, mutect2, varscan2
- PRMT7 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59834618; called by muse, mutect2
- PRSS1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs766731858, COSV100298009, COSV61195597; ClinVar: uncertain significance; called by muse, varscan2
- SBNO2 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62322358; called by muse, mutect2, varscan2
- SCFD1 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 125/563 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as rs780100858, COSV61725729; called by muse, mutect2, varscan2
- SEMG2 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 106/326 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV65647762; called by muse, mutect2, varscan2
- SIAH2 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57262658; called by muse, mutect2
- SLC2A5 | c.1117C>G p.P373A | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV66237590; called by muse, mutect2
- SSTR1 | c.494C>A p.A165E | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV57456706, COSV57457031; called by muse, mutect2, varscan2
- SYNE2 | c.12779A>G p.E4260G | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV59961581; called by muse, mutect2, varscan2
- SYT1 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 43/127 reads (34%) | catalogued as rs1377017458, COSV54063068; called by muse, mutect2, varscan2
- THBS4 | c.275T>C p.M92T | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.104); catalogued as COSV63470316; called by muse, mutect2, varscan2
- TM9SF2 | c.970C>G p.R324G | Missense Mutation (SNP) | VAF 114/403 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100899695, COSV64507190; called by muse, mutect2, varscan2
- VPS13C | c.6814A>T p.I2272L (on ENST00000644861 / NM_020821.3; = p.I2229L on NM_017684.5) | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV51349794; called by muse, mutect2, varscan2
- ZNF347 | c.2205del p.K735Nfs*71 | Frame Shift Del (DEL) | VAF 88/260 reads (34%) | catalogued as rs747329533; called by mutect2, varscan2
- ZNF808 | c.2303G>C p.C768S | Missense Mutation (SNP) | VAF 93/315 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63120961; called by muse, mutect2, varscan2
- PTEN | c.981del p.A328Qfs*16 | Frame Shift Del (DEL) | VAF 48/182 reads (26%) | called by mutect2, pindel, varscan2
- TRGV3 | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2
- ABCC6 | c.1593C>G p.L531= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV52746503; called by muse, mutect2, varscan2
- ALPK2 | c.4704T>A p.P1568= | Silent (SNP) | VAF 30/208 reads (14%) | catalogued as COSV64495117; called by muse, mutect2, varscan2
- ARMCX3 | c.381T>C p.L127= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV57871268; called by muse, mutect2, varscan2
- BDP1 | c.1338A>G p.S446= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as COSV62433129; called by muse, mutect2, varscan2
- CLDN17 | c.408G>A p.P136= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs201580398, COSV54522709; called by muse, mutect2, varscan2
- CNOT9 | c.199T>C p.L67= | Silent (SNP) | VAF 71/197 reads (36%) | catalogued as rs1356437727, COSV55301113; called by muse, mutect2, varscan2
- IQGAP2 | c.330A>G p.T110= | Silent (SNP) | VAF 22/391 reads (6%) | catalogued as COSV57178118; called by muse, mutect2
- LSM14B | c.411C>T p.A137= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs747700374, COSV53380837; called by muse, mutect2, varscan2
- NFKB2 | c.126C>T p.I42= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs976488499, COSV51870843, COSV51874273; called by muse, mutect2, varscan2
- OR8J3 | c.729G>A p.S243= | Silent (SNP) | VAF 98/313 reads (31%) | catalogued as rs774862778, COSV56879581, COSV56879736; called by muse, mutect2, varscan2
- PGBD5 | c.522C>T p.F174= (on ENST00000525115; = p.F243= on NM_001258311.2) | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs772495531, COSV58412840; called by muse, mutect2, varscan2
- RYR1 | c.13566C>T p.P4522= | Silent (SNP) | VAF 14/272 reads (5%) | catalogued as rs1470487879, COSV62104830; called by muse, mutect2
- SLITRK2 | c.120C>T p.N40= | Silent (SNP) | VAF 76/139 reads (55%) | catalogued as COSV59427014; called by muse, mutect2, varscan2
- TULP4 | c.2844C>T p.V948= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV65578828; called by muse, mutect2, varscan2
